Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4970, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4970-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

with a 3.8 right lower pole renal mass.

TCGA-BP-4970

Specimens Submitted:

- 1: SP:Kidney, right, total nephrectomy
- 2: SP:Perihilar lymph node, right, excision

DIAGNOSIS:

1. SP:Kidney, right, total nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
the tumor is partially cystic

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 3.5 cm.

Local Invasion (for renal cortical types):

Not identified
the tumor abuts the renal sinus

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

A small (0.5 cm) renal medullary fibroma is present

Adrenal Gland:

Not identified

Lymph Nodes:

Free of tumor
Number of metastatic nodes:2

Staging for renal cell carcinoma/oncocytoma:

PT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. SP:Perihilar lymph node, right, excision

Lymph Nodes:

[page 2 of 2]
Not identified
Benign fibroadipose tissue

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh labeled "right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 253 g in total. The kidney measures 12.5 x 8.0 x 4.0 cm. The attached ureter measures 1.5 cm in length and 0.4 cm in diameter. The attached renal vein measures 1.0 cm in length and 0.3 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal 3.5 x 3.0 x 2.2 cm well circumscribed mass in the lower pole adjacent to the renal sinus. The cut surface of the mass is solid and cystic, tan yellow and hemorrhagic. A second 0.5 x 0.4 x 0.3 cm tan nodule distal to the first mass is identified with a firm cut surface. Sections through the remainder of the kidney reveal a pink brown parenchyme, with a well-defined cortico-medullary junction. The cortex measures 0.7 cm and the calyces appear normal. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

T2 -- second nodule

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- representative of kidney

2). The specimen is received in formalin, labeled "right perihilar lymph node" and consists of a portion of adipose tissue. No lymph node identified. Entirely submitted.

Summary of sections:

U- possible lymph node

Summary of Sections:

Part 1: SP:Kidney, right, total nephrectomy

Block	Sect. Site	PCs
2	rp	2
3	t	3
1	t2	1
2	thf	2
2	tk	2
2	tsf	2
1	uvm	1

Part 2: SP:Perihilar lymph node, right, excision

Block	Sect. Site	PCs
2	u	2

Source: NCI Genomic Data Commons file c8173423-47f2-4ff2-91d6-1e8ecca356b2 (TCGA-BP-4970.EF2070AB-E768-491C-BBF0-035E45898F42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).